TCGA case TCGA-G4-6298 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab9cc98a-86ae-4913-bcb2-cc3aeff8abb1

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 0 days.

Diagnoses (2; GDC holds 3 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 37; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Initial disease status: Progressive Disease; Days to treatment start: 0 days; Days to treatment end: 0 days; Number of cycles: 4; Treatment dose: 1,760 mg; Prescribed dose: 440; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 0 days; Days to treatment end: 0 days; Number of cycles: 4; Treatment dose: 704 mg; Prescribed dose: 176; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 90 years or older (exact value withheld by GDC); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (1 entry)
- Day 0 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 0 days.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59.4 kg.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 3; Intermediate dimension: 1; Shortest dimension: 1.
  Slide TCGA-G4-6298-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-G4-6298-01A-01-TS1: Section location: Top; Percent tumor cells: 54; Percent tumor nuclei: 60; Percent normal cells: 35; Percent necrosis: 1; Percent stromal cells: 10.
- Sample TCGA-G4-6298-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6298-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-G4-6298-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Erbitux; Therapy regimen: Progression.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy prostate. Unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 715 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 715 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 291 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G4-6298-01A-11D-1717-01): tumor purity 0.6, ploidy 1.98, whole-genome doublings 0.
